Gene-level copy-number profile of tumor specimen TCGA-WC-A888-01A from TCGA case TCGA-WC-A888, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 77.0 years (28,117 days).
Specimen TCGA-WC-A888-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UVM.1d8ecc9b-e51a-48c2-93a7-86acf98b6198.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WC-A888-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 353 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5db9c697-53d3-41f2-9b0c-273371618ae6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6,128; copy number 1: 1,444; copy number 2: 49,701; copy number 3: 1,331; copy number 4: 5; copy number 5: 228; copy number 6: 1,332; copy number 7: 101.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WC-A888-01A-11D-A39V-01): tumor purity 1, ploidy 2.04, whole-genome doublings 0.

Caution: 3,187 autosomal genes are at 0 copies in this file, far more than a typical tumor; the lists below are given as recorded.

Homozygous deletions (total copy number 0; autosomes only): 3,187 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–129,918,575, 1,998 genes (broad region; genes not listed).
- chr3:129,998,531–198,222,513, 1,185 genes (broad region; genes not listed).
- chr4:83,233,512–83,247,213, 2 genes (within-gene range 0–2): AC114781.2, AC114781.3.
- chr9:11,313,397–11,436,244, 1 gene (within-gene range 0–2): AL355672.1.
- chr11:58,387,583–58,388,486, 1 gene: OR5B15P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,661 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5–6 (broad region; genes not listed).
- chr14:105,785,505–106,360,324, 101 genes, copy number 7 (broad region; genes not listed).
- chr15:31,765,743–32,587,613, 26 genes, copy number 5: DEPDC1P1, AC026951.1, CHRNA7, AC079969.1, Y_RNA, AC068448.1, AC139426.3, RNU6-18P, AC139426.1, AC139426.2, AC139426.4, DNM1P31, GOLGA8K, RN7SL185P, AC135983.1, ULK4P1, U8, DNM1P32, GOLGA8O, RN7SL539P, AC135983.5, AC135983.4, AC135983.3, AC135983.2, LINC02256, AC123768.3.

Autosomal genes at a single copy (total copy number 1): 1,444. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
